Surgical pathology report (de-identified scan), TCGA case TCGA-56-7730, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-7730-01A (Primary Tumor).

[page 1 of 4]
Results

Specimen Information

Component Results

SURGICAL PANEL:

Final Report

DIAGNOSIS

A) RIGHT PARATRACHEAL LYMPH NODE, EXCISION:

1. Benign lymph node
2. No evidence of metastatic carcinoma

B) RIGHT PARATRACHEAL LYMPH NODES, STATION 4R LYMPH NODE, EXCISION:

1. Four benign lymph nodes
2. No evidence of metastatic carcinoma

C) STATION 10R LYMPH NODE, RIGHT CHEST, EXCISION:

1. Benign lymph node
2. No evidence of metastatic carcinoma

D) THORACIC LYMPH NODE, STATION 11R, EXCISION:

1. Benign lymph node
2. No evidence of metastatic carcinoma

E) TRACHEOBRONCHIAL ANGLE LYMPH NODE, EXCISION:

1. Benign lymph node
2. No evidence of metastatic carcinoma

F) LUNG, RIGHT UPPER LOBE, LOBECTOMY:

1. Moderately to poorly differentiated invasive squamous cell carcinoma forming a mass measuring 6.5 x 4.3 x 3 cm
2. Tumor infiltrates up to but not within visceral pleura
3. Focal in-situ and superficially invasive squamous cell carcinoma is present in the en face section of the proximal bronchial resection margin
4. Patchy hemorrhage and post-obstructive pneumonia present in non-involved pulmonary parenchyma
5. Ten (10) benign right hilar lymph nodes

COMMENT

Final TNM: pT2bN0M0

stage: IIA

MACROSCOPIC

SPECIMEN TYPE

Lobectomy

TUMOR SITE

Right Lung-Upper Lobe

[page 2 of 4]
TUMOR SIZE
6.5 X 4.3 X 3.0 cm
TUMOR FOCALITY
Unifocal

MICROSCOPIC
HISTOLOGIC TYPE
Squamous cell carcinoma
HISTOLOGICAL GRADE
(moderately differentiated)
VISCERAL PLEURAL INVASION
Not identified
LYMPHATIC VASCULAR INVASION
Absent
TREATMENT EFFECT
Not applicable
TUMOR EXTENSION
Not applicable
MARGINS
Margins involved by tumor (Bronchial)

PATHOLOGIC STAGING
EXTENT OF INVASION
pT2b. (Tumor greater than 5 cm, but 7 cm or less in greatest dimension)
REGIONAL LYMPH NODES
pN0. (No regional lymph node metastasis)
Total nodes: 18
Total positive nodes: 0
N1 nodes: 12
N1 positive nodes: 0
N2 nodes: 6
N2 positive nodes: 0
N2 sites sampled:
Station 4: Lower paratracheal nodes
DISTANT METASTASIS
pM0. (No distant metastasis)
PATHOLOGIC STAGE Summary
Final TNM: pT2bN0M0
stage: IIA
** The pathologic stage presumes no distant metastasis.

CLINICAL INFORMATION
History of lung cancer

SPECIMEN/GROSS DESCRIPTION
A) SOURCE: Right paratracheal lymph node
The specimen is received fresh from the OR labeled "right paratracheal lymph node" and consists of a 0.3-0.4 cm diameter adipose tissue with a possible 0.2-0.3 cm lymph node frozen in toto on one block.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Negative for tumor" is rendered by

B) SOURCE: Right paratracheal lymph nodes #2 4R lymph node

[page 3 of 4]
[REDACTED]

Received fresh labeled "right paratracheal lymph node #2 4R lymph nodes" consists of multiple anthracotic lymph node fragments and fat aggregating to 3 cm in greatest dimension. The tissue is entirely submitted on two chucks for frozen section diagnosis.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Negative" is [REDACTED]

C) SOURCE: Right chest 10 R lymph node
Labeled "10 R node right chest" is a 0.6 cm anthracotic apparent lymph node. The specimen is entirely submitted in one cassette.

D) SOURCE: Thoracic 11 R lymph node
Received fresh labeled "11 R lymph node thoracic" is a 1.5 cm aggregate of black anthracotic apparent lymph node fragments in fat. It is entirely submitted on one chuck for frozen section diagnosis.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Negative" is [REDACTED]

E) SOURCE: Tracheal lymph node bronchial angle
The specimen is received fresh from the OR labeled "tracheal bronchial angle lymph node." It consists of a 1.3 cm in diameter black-red lymph node sectioned into four pieces and entirely frozen on one block.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Negative" is rendered [REDACTED]

F) SOURCE: Right upper lobe lung
The specimen is received fresh labeled "right upper lobe." It consists of a tan-pink, 19 x 15 x 5.5 cm portion of right upper lobe. The bronchial margin is patent and a tan-pink tumor is seen 0.7 cm distal to the margin. There is an intact, 12-cm staple line. The pleural surface is tan-pink and mottled with a palpable mass seen just superior to the bronchus. This area is inked blue. The staple line is removed, the specimen is sectioned. Cut section of the specimen reveals a white lobulated tumor mass corresponding to that seen at the mainstem bronchus and palpated. There are dilated airways throughout the specimen that are filled with thick yellow-tan mucoid material surrounded by tan-pink spongy mildly anthracotic parenchyma. The tumor measures 6.5 x 4.3 x 3 cm. The tumor is 1.5 cm from the nearest orange-inked staple line. No additional satellite lesions are seen. A photograph is taken. Tissue is banked for possible ancillary studies. The tumor extends to the inked pleural surface but does not grossly extend through it. The hilum displays a 3-cm aggregate of lymph nodes.

Representative sections are submitted in 14 cassettes as follows:

1. Mainstem bronchus margin
2. Vascular margin
3. Closest staple line, no tumor
- 4-5. Mainstem bronchus and tumor
6. Tumor to inked pleura
- 7-8. Random tumor
- 9-11. Random parenchyma with no tumor
- 12-14. Hilar lymph nodes
- [REDACTED]
- [REDACTED]

[page 4 of 4]
[REDACTED]

This case is accessioned in [REDACTED]

Gross dictation by [REDACTED]

MICROSCOPIC

A-E) The microscopic appearance substantiates the diagnosis.

F) Sections through the right upper lobe tumor mass confirm the presence of a moderately to poorly differentiated infiltrating squamous cell carcinoma forming a mass measuring 6.5 cm in greatest dimension. Tumor infiltrates up to but not within contiguous visceral pleura. An en face section from the proximal bronchial resection margin demonstrates focal in-situ and superficially invasive squamous cell carcinoma within bronchial mucosa. The non-involved pulmonary parenchyma demonstrates areas of post-obstructive pneumonia and patchy hemorrhage. Ten benign hilar lymph nodes are included.

[REDACTED]

Interpreted at [REDACTED]

Lab and Collection

GROSS AND MICROSCOPIC SURGICAL PANEL [REDACTED]
Information

Lab and Collection

Result History

GROSS AND MICROSCOPIC SURGICAL PANEL [REDACTED]
Report.

Order Result History

Lab Status

Order Complete [3]

Result Information

Result Date and Time

Status

Provider Status

Final result

Ordered

Lab Information

Lab

Order Details

Parent Order ID

Child Order ID

Entry Date

Specimen Information

Specimen Source

Collection Date

Collection Time

Other

Audit Trail

Source: NCI Genomic Data Commons file 8197d399-66c3-4bda-9fc0-10e28c06a897 (TCGA-56-7730.A8561DCF-B71E-4F28-A8BB-F0CE96066934.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).